Somatic mutation profile of tumor specimen MP2PRT-PAUSVA-TMP1-A (aliquot MP2PRT-PAUSVA-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUSVA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,150 days).
Specimen MP2PRT-PAUSVA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a425ef05-4365-4893-bae3-2c26523f0140.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUSVA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUSVA-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ead7e3e3-de6e-4ad4-ba3d-6d7bb5924af2

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 110/349 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PDE4A | c.2050C>T p.R684W (on ENST00000380702 / NM_001111307.2; = p.R445W on NM_006202.3) | Missense Mutation (SNP) | VAF 146/294 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs199552753, COSV53357169; called by muse, varscan2
- SHROOM3 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99935670; called by muse, mutect2, varscan2
- IL17C | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 188/634 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SCX | c.212_225delinsCGGCACACGGC p.G71_R75delinsAAHG | In Frame Del (DEL) | VAF 37/227 reads (16%) | called by pindel, varscan2*
- AOX1 | c.2019G>A p.Q673= | Silent (SNP) | VAF 77/168 reads (46%) | called by muse, mutect2, varscan2
- GRIN2A | c.4224G>A p.T1408= | Silent (SNP) | VAF 151/504 reads (30%) | catalogued as rs773175225; called by muse, mutect2, varscan2
- MROH7 | c.1818G>A p.P606= | Silent (SNP) | VAF 88/174 reads (51%) | catalogued as rs763219467; called by muse, mutect2, varscan2
- PKHD1 | c.4812G>A p.T1604= | Silent (SNP) | VAF 135/407 reads (33%) | catalogued as rs780533224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
